Surgical pathology report (de-identified scan), TCGA case TCGA-A6-2675, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-2675-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Sigmoid colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Sigmoid cancer

GROSS DESCRIPTION

Received fresh, subsequently fixed in formalin labeled "sigmoid colon" is a 17 cm. long portion of colon which is opened on both ends. The serosa is pink-tan smooth glistening and the specimen is predominantly covered with abundant yellow lobular fat and pink-tan smooth glistening serosa. The specimen is opened to show pink-tan smooth glistening mucosa with an average circumference of 4 cm. The specimen shows a 3.2 x 2.5 x 0.5 cm. tumor which shows ulcerated center and raised borders. The cut surface of this shows gross invasion into the muscularis propria and comes within 7.5 cm. of the radial margin; however, there is an umbilication near the serosa and the fat meet. This is inked and the tumor comes within 0.7 cm. of this area. No other discrete gross lesions are identified. Lymph nodes are grossly identified in the fat. Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY: 1 - representative luminal margins; 2 - representative section of tumor to fat and serosa; 3-5 - additional representative sections of tumor to fat; 6 - representative radial margins; 7 - 4 possible lymph nodes; 8 - 6 possible lymph nodes; 9

6 possible lymph nodes; 10 - 3 possible lymph nodes. RS-10

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma.

Histologic grade: Moderately differentiated.

Primary tumor (pT): Tumor invades through the muscularis propria to

[page 2 of 2]
MICROSCOPIC DESCRIPTION

the junction of the muscularis propria and serosa (pT3).
Proximal margin: Negative.
Distal margin: Negative.
Circumferential (radial) margin: Negative.
Vascular invasion: Negative.
Regional lymph nodes (pN): Eleven mesenteric lymph nodes are
negative for metastatic carcinoma (pN0).
Non-lymph node pericolic tumor: Absent.
Distant metastasis (pM): Cannot be assessed (pMX).

5

DIAGNOSIS

Colon, sigmoid, segmental resection:
Invasive moderately differentiated colonic adenocarcinoma
extending through the muscularis propria to the junction of the
muscularis propria and serosa.
Proximal, distal and radial margins of resection are free of
tumor.
Eleven mesenteric lymph nodes negative for metastatic carcinoma
(0/11).

Source: NCI Genomic Data Commons file 2cba040f-bb76-43af-8de7-ed83174b4b7f (TCGA-A6-2675.C9A27850-8295-4E69-AB9E-A9765650FCEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).